Somatic mutation profile of tumor specimen MMRF_1645_2_BM_CD138pos (aliquot MMRF_1645_2_BM_CD138pos_T1_KHS5U_L12927) from MMRF case MMRF_1645, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 36.1 years (13,200 days).
Specimen MMRF_1645_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6401002d-2a8f-40f2-9e0e-392e081ad0c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1645_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1645_1_PB_Whole_C3_KBS5U_L04834; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab053926-ef3d-4991-b4d1-21c3c066ec11

The open-access MAF lists 56 somatic variants for this specimen: 18 protein-altering or splice-affecting, 12 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 18, Missense Mutation 16, Silent 12, 5'Flank 4, Intron 3, Nonsense Mutation 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGAP1 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs374021595; called by muse, mutect2, varscan2
- DLC1 | c.3250G>A p.V1084M (on ENST00000276297 / NM_001348081.2; = p.V647M on NM_006094.5) | Missense Mutation (SNP) | VAF 104/243 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as rs774780095, COSV52297787; called by muse, mutect2, varscan2
- EYS | c.2288G>C p.W763S | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65563346; called by muse, mutect2, varscan2
- IGHV2-70D | c.341A>T p.Y114F | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1414572352; called by muse, mutect2
- IGLV3-1 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as rs560070339; called by muse, mutect2, varscan2
- KIF3B | c.1450C>T p.H484Y | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV65227805; called by muse, mutect2, varscan2
- OR10G9 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV66685778; called by muse, mutect2
- OR2V1 | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575995595, COSV61459090; called by muse, mutect2, varscan2
- OR2V1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1309669997; called by muse, mutect2, varscan2
- APCS | c.637G>T p.G213* | Nonsense Mutation (SNP) | VAF 90/219 reads (41%) | called by mutect2, varscan2
- BEST3 | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DUSP2 | c.285T>G p.S95R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- EGR1 | c.230G>A p.S77N | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT4 | c.6741T>G p.I2247M | Missense Mutation (SNP) | VAF 162/404 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- OR2V1 | c.529C>T p.H177Y | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- PCDH9 | c.907T>G p.F303V | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRSS21 | c.770G>T p.S257I | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEPTIN10 | c.40T>A p.S14T | Missense Mutation (SNP) | VAF 130/379 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL1 | c.3162G>A p.S1054= | Silent (SNP) | VAF 147/278 reads (53%) | called by muse, mutect2, varscan2
- BCL7A | c.51T>C p.D17= | Silent (SNP) | VAF 50/136 reads (37%) | catalogued as COSV99946945; called by muse, mutect2, varscan2
- DMRTA2 | c.717G>A p.S239= | Silent (SNP) | VAF 72/230 reads (31%) | catalogued as rs747667218, COSV101288891; called by muse, mutect2, varscan2
- IGLL5 | c.108T>C p.H36= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs561199169, COSV73251103; called by muse, mutect2, varscan2
- ITGA9 | c.1407C>T p.I469= | Silent (SNP) | VAF 42/154 reads (27%) | catalogued as rs774482781; called by muse, mutect2, varscan2
- LAMP5 | c.207T>G p.P69= | Silent (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- MCF2L | c.732G>A p.T244= (on ENST00000375608; = p.T212= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/129 reads (39%) | catalogued as rs757989358, COSV65053524; called by muse, mutect2, varscan2
- OR2V1 | c.555A>G p.L185= | Silent (SNP) | VAF 40/103 reads (39%) | called by muse, varscan2
- OR2V1 | c.96T>C p.V32= | Silent (SNP) | VAF 48/134 reads (36%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.9045G>A p.P3015= | Silent (SNP) | VAF 79/258 reads (31%) | catalogued as rs142162700; called by muse, mutect2, varscan2
- SOCS6 | c.63A>G p.E21= | Silent (SNP) | VAF 36/99 reads (36%) | called by muse, mutect2, varscan2
- URB1 | c.3282G>A p.P1094= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as rs377170267; called by muse, mutect2, varscan2
- C2orf69 | c.*2184G>C | 3'UTR (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- CFHR3 | c.614-188C>T | Intron (SNP) | VAF 5/72 reads (7%) | catalogued as COSV100807359; called by muse, mutect2
- DHRS13 | c.*360T>G | 3'UTR (SNP) | VAF 35/119 reads (29%) | called by muse, mutect2, varscan2
- DIO2 | c.*924del | 3'UTR (DEL) | VAF 26/75 reads (35%) | catalogued as rs896407541; called by mutect2, varscan2
- DLG4 | chr17:7219051 T>G | 5'Flank (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- DNER | c.*392A>G | 3'UTR (SNP) | VAF 40/96 reads (42%) | called by muse, mutect2, varscan2
- FAM13C | c.62+1320G>A | Intron (SNP) | VAF 74/204 reads (36%) | called by muse, mutect2, varscan2
- FAM53B | c.*2579A>T | 3'UTR (SNP) | VAF 24/75 reads (32%) | called by muse, mutect2, varscan2
- FAM83A | c.*491T>A | 3'UTR (SNP) | VAF 21/73 reads (29%) | called by muse, mutect2, varscan2
- FTO | c.*78G>A | 3'UTR (SNP) | VAF 10/30 reads (33%) | called by mutect2, varscan2
- FZD3 | c.*10747A>G | 3'UTR (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- GATM | chr15:45378692 G>C | 5'Flank (SNP) | VAF 44/124 reads (35%) | called by muse, mutect2, varscan2
- GUCY1B1 | c.*1157C>T | 3'UTR (SNP) | VAF 22/51 reads (43%) | catalogued as rs1311691013; called by muse, mutect2, varscan2
- IKZF2 | c.*1913A>T | 3'UTR (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- KLHL8 | c.*2713A>C | 3'UTR (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- NCAPD3 | chr11:134224326 del GG | 5'Flank (DEL) | VAF 51/220 reads (23%) | called by mutect2, pindel, varscan2
- NHS | c.*2994A>T | 3'UTR (SNP) | VAF 27/33 reads (82%) | called by muse, mutect2, varscan2
- NKX2-8 | c.*887A>C | 3'UTR (SNP) | VAF 40/106 reads (38%) | called by muse, mutect2, varscan2
- PIM1 | c.-90C>G | 5'UTR (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- PLA2G2D | c.*1226C>T | 3'UTR (SNP) | VAF 37/122 reads (30%) | called by muse, mutect2, varscan2
- RGS3 | c.*361G>A | 3'UTR (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2, varscan2
- SNORD116-7 | chr15:25065260 A>G | 5'Flank (SNP) | VAF 27/54 reads (50%) | catalogued as rs1350706389; called by muse, mutect2, varscan2
- SPTLC3 | c.*1661dup | 3'UTR (INS) | VAF 19/65 reads (29%) | called by mutect2, pindel, varscan2
- ZNF451 | c.3070+368C>T | Intron (SNP) | VAF 17/61 reads (28%) | catalogued as rs923314314; called by muse, mutect2, varscan2
- ZNF704 | c.*2781G>A | 3'UTR (SNP) | VAF 24/54 reads (44%) | catalogued as rs781631102; called by mutect2, varscan2
- ZNF716 | c.*3173A>T | 3'UTR (SNP) | VAF 4/82 reads (5%) | catalogued as rs1433508925; called by muse, mutect2
